Somatic mutation profile of tumor specimen TCGA-YS-A95B-01A (aliquot TCGA-YS-A95B-01A-11D-A39R-32) from TCGA case TCGA-YS-A95B, project TCGA-MESO (Mesothelioma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Epithelioid mesothelioma, malignant; Tissue or organ of origin: Pleura, NOS; AJCC pathologic stage: Stage IV; Age at diagnosis: 28.8 years (10,510 days).
Specimen TCGA-YS-A95B-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 30e4ee31-ffec-4232-b971-e39bd6091d77.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-YS-A95B-10A (Blood Derived Normal), aliquot TCGA-YS-A95B-10A-01D-A39U-32; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9972fcf4-0a33-48ea-80d9-4a89970e19a9

The open-access MAF lists 17 somatic variants for this specimen: 11 protein-altering or splice-affecting, 6 silent.
By variant classification: Missense Mutation 9, Silent 6, Nonsense Mutation 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EPHA5 | c.3020G>A p.R1007Q | Missense Mutation (SNP) | VAF 32/83 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.811); catalogued as rs145811811, COSV56640997; called by muse, mutect2, varscan2
- FOXF2 | c.465C>G p.N155K | Missense Mutation (SNP) | VAF 47/252 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV52525492; called by muse, mutect2, varscan2
- GPR149 | c.1786A>T p.S596C | Missense Mutation (SNP) | VAF 46/138 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV67669165; called by muse, mutect2, varscan2
- PCDHGB3 | c.68C>T p.S23F | Missense Mutation (SNP) | VAF 30/69 reads (43%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.635); catalogued as COSV53940181; called by muse, mutect2, varscan2
- PRAM1 | c.910G>T p.V304L | Missense Mutation (SNP) | VAF 73/195 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0.35); catalogued as COSV55316412; called by muse, mutect2, varscan2
- PTEN | c.736C>T p.P246S | Missense Mutation (SNP) | VAF 27/74 reads (36%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.767); catalogued as COSV100909503; called by muse, mutect2, varscan2
- ZSWIM4 | c.1858G>A p.A620T | Missense Mutation (SNP) | VAF 29/121 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs773972459; called by muse, mutect2, varscan2
- MCF2L | c.499C>A p.R167S (on ENST00000375608; = p.R135S on NM_024979.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 38/111 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- NIN | c.4857C>A p.C1619* (on ENST00000382041 / NM_182946.1; = p.C906* on NM_016350.4) | Nonsense Mutation (SNP) | VAF 46/78 reads (59%) | called by muse, mutect2, varscan2
- SMCHD1 | c.5606G>T p.S1869I | Missense Mutation (SNP) | VAF 24/80 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); called by muse, mutect2, varscan2
- TBX22 | c.456T>C p.Y152= | Splice Region (SNP) | VAF 19/48 reads (40%) | called by muse, mutect2, varscan2
- GRK4 | c.21G>C p.V7= | Silent (SNP) | VAF 45/121 reads (37%) | called by muse, mutect2, varscan2
- IL31RA | c.1533C>T p.Y511= | Silent (SNP) | VAF 9/83 reads (11%) | catalogued as rs750250796; called by muse, mutect2, varscan2
- IRGQ | c.1149G>C p.G383= | Silent (SNP) | VAF 12/341 reads (4%) | called by muse, mutect2
- MMP13 | c.57C>A p.A19= | Silent (SNP) | VAF 14/68 reads (21%) | called by muse, mutect2, varscan2
- MROH6 | c.1374T>A p.G458= | Silent (SNP) | VAF 9/25 reads (36%) | called by muse, mutect2
- PPP1R21 | c.1899T>C p.A633= | Silent (SNP) | VAF 24/53 reads (45%) | catalogued as rs375416872; called by muse, mutect2, varscan2
